Somatic mutation profile of tumor specimen TCGA-2G-AAH8-01A (aliquot TCGA-2G-AAH8-01A-11D-A42Y-10) from TCGA case TCGA-2G-AAH8, project TCGA-TGCT (Testicular Germ Cell Tumors). Sex at birth: male; Vital status: Alive; Primary diagnosis: Seminoma, NOS; Tissue or organ of origin: Testis, NOS; AJCC pathologic stage: Stage IIIC; Age at diagnosis: 45.7 years (16,687 days).
Specimen TCGA-2G-AAH8-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e0c9e6d5-8b5f-49b4-802a-97ad5050f828.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-2G-AAH8-10A (Blood Derived Normal), aliquot TCGA-2G-AAH8-10A-01D-A433-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1e59df84-0d2b-4055-afa7-1fc4efa2a1b0

The open-access MAF lists 26 somatic variants for this specimen: 23 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 21, Silent 2, Intron 1, Nonsense Mutation 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.182A>T p.Q61L | Missense Mutation (SNP) | VAF 25/215 reads (12%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.631); catalogued as rs121913240, COSV55498739, COSV55504296, COSV55508574; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PIK3CB | c.3200A>T p.D1067V | Missense Mutation (SNP) | VAF 44/170 reads (26%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV56683107, COSV56689255; called by muse, mutect2, varscan2
- ELN | c.886G>T p.A296S | Missense Mutation (SNP) | VAF 32/179 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.406); catalogued as COSV52714713; called by muse, mutect2, varscan2
- HSP90AA1 | c.530-9_530-7del | Splice Region (DEL) | VAF 31/124 reads (25%) | catalogued as rs776932150; called by mutect2, pindel, varscan2
- MEGF10 | c.1588C>T p.Q530* | Nonsense Mutation (SNP) | VAF 13/56 reads (23%) | catalogued as COSV57245756; called by muse, mutect2, varscan2
- MUC5B | c.11693C>G p.T3898R | Missense Mutation (SNP) | VAF 54/237 reads (23%) | SIFT tolerated (0.23); PolyPhen benign (0.081); catalogued as rs1403557968; called by muse, mutect2, varscan2
- ATAD2 | c.458A>C p.E153A | Missense Mutation (SNP) | VAF 72/352 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.207); called by muse, varscan2
- DCTN2 | c.841G>A p.A281T (on ENST00000548249 / NM_001261413.2; = p.A286T on NM_006400.4) | Missense Mutation (SNP) | VAF 39/208 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FBXO45 | c.223A>G p.N75D | Missense Mutation (SNP) | VAF 25/72 reads (35%) | SIFT tolerated (0.42); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- FLG | c.6882C>A p.H2294Q | Missense Mutation (SNP) | VAF 78/314 reads (25%) | SIFT tolerated (0.72); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- GALNTL5 | c.1261G>C p.G421R | Missense Mutation (SNP) | VAF 32/187 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.145); called by muse, mutect2, varscan2
- GPX1 | c.76G>T p.G26C | Missense Mutation (SNP) | VAF 31/104 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- GSTK1 | c.143T>A p.M48K | Missense Mutation (SNP) | VAF 23/199 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); called by muse, mutect2, varscan2
- IGF2BP2 | c.490T>A p.S164T | Missense Mutation (SNP) | VAF 52/186 reads (28%) | SIFT tolerated (0.49); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- LMNB1 | c.1746C>A p.S582R | Missense Mutation (SNP) | VAF 51/229 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- MDN1 | c.2700C>G p.N900K | Missense Mutation (SNP) | VAF 21/103 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); called by muse, mutect2, varscan2
- ME1 | c.898C>G p.Q300E | Missense Mutation (SNP) | VAF 13/104 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- NRIP2 | c.335A>T p.K112M | Missense Mutation (SNP) | VAF 12/146 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- OTUD4 | c.2311C>A p.Q771K (on ENST00000447906 / NM_001366057.1; = p.Q706K on NM_001102653.1) | Missense Mutation (SNP) | VAF 33/95 reads (35%) | SIFT tolerated (0.16); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- PPFIA1 | c.3500C>G p.T1167S | Missense Mutation (SNP) | VAF 27/64 reads (42%) | SIFT tolerated (0.44); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- RAN | c.50G>A p.G17D | Missense Mutation (SNP) | VAF 43/233 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RSF1 | c.394G>C p.D132H | Missense Mutation (SNP) | VAF 28/85 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- SELENOI | c.63T>G p.S21R | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- BRAT1 | c.1356C>G p.V452= | Silent (SNP) | VAF 94/259 reads (36%) | called by muse, mutect2, varscan2
- TBC1D32 | c.2502A>C p.I834= | Silent (SNP) | VAF 68/375 reads (18%) | called by muse, mutect2, varscan2
- GALE | c.122-45C>A | Intron (SNP) | VAF 31/104 reads (30%) | called by muse, mutect2, varscan2
